Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHW, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHW-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 6.1 cm; no invasion of rete testis; no angio-invasion;
no invasion of tunica albuginea; epididymis free of tumor; surgical margin spermatic cord free
of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3

Seminoma NOS 9061/3
Site: Rete Testis NOS 9062.9
J4 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 84999991-55ec-466d-a2ae-7e48adfdf16b (TCGA-2G-AAHW-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).